Somatic mutation profile of tumor specimen TCGA-B4-5377-01A (aliquot TCGA-B4-5377-01A-01D-1501-10) from TCGA case TCGA-B4-5377, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.8 years (25,115 days).
Specimen TCGA-B4-5377-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f41c8225-8856-4350-b28d-3d21806e47af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B4-5377-10A (Blood Derived Normal), aliquot TCGA-B4-5377-10A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5416b61d-9bbe-404e-bb6a-876242167f44

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 29, Silent 14, Frame Shift Del 6, Splice Site 3, Nonsense Mutation 3, Splice Region 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGMAT | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148899500; called by muse, mutect2, varscan2
- ASTE1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.377); catalogued as COSV53909813; called by muse, mutect2, varscan2
- CLDN16 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 220/697 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV53228904; called by muse, mutect2, varscan2
- CLK1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.332); catalogued as COSV58433693, COSV58435209; called by muse, mutect2, varscan2
- COL6A2 | c.789C>A p.Y263* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as COSV56012577; called by muse, mutect2, varscan2
- CTSW | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV57172906; called by muse, mutect2, varscan2
- DIP2B | c.2266T>G p.S756A | Missense Mutation (SNP) | VAF 159/447 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV56589270; called by muse, mutect2, varscan2
- DNAH3 | c.2848C>G p.P950A | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV54540710; called by muse, mutect2
- DNER | c.975C>A p.C325* | Nonsense Mutation (SNP) | VAF 72/204 reads (35%) | catalogued as COSV59172756; called by muse, mutect2, varscan2
- EGLN1 | c.891+2T>C p.X297_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100791310; called by muse, mutect2
- FBXO27 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.887); catalogued as COSV53072305, COSV53072898; called by muse, mutect2, varscan2
- GABRG2 | c.1256C>T p.T419I (on ENST00000361925 / NM_001375343.1; = p.T379I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV62720917; called by muse, mutect2, varscan2
- IFT80 | c.1064G>T p.C355F | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58450826; called by muse, mutect2
- KCNB2 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101578771, COSV73051861; called by muse, mutect2, varscan2
- KNG1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV53980185; called by muse, mutect2
- MCM10 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV66332980, COSV66334474; called by muse, mutect2, varscan2
- MED12L | c.6220del p.Q2074Sfs*63 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as COSV99850937; called by mutect2, pindel, varscan2
- MROH1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV58192408; called by muse, mutect2, varscan2
- MYL2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV57407807; called by muse, mutect2, varscan2
- PBRM1 | c.529-2A>T p.X177_splice | Splice Site (SNP) | VAF 44/163 reads (27%) | catalogued as COSV56294382; called by muse, mutect2, varscan2
- PCM1 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 81/177 reads (46%) | catalogued as COSV61518286; called by muse, mutect2, varscan2
- PCM1 | c.1592A>T p.E531V | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61518295; called by muse, mutect2, varscan2
- PJA2 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63274054; called by muse, mutect2, varscan2
- PRPS2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 158/451 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as COSV66126536; called by muse, mutect2, varscan2
- PSG2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 31/534 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100283617, COSV61546014; called by muse, mutect2
- ROBO2 | c.2856T>C p.D952= | Splice Region (SNP) | VAF 12/134 reads (9%) | catalogued as COSV59930007; called by muse, mutect2
- SEMA3D | c.1742T>A p.I581N | Missense Mutation (SNP) | VAF 128/405 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as COSV52400366; called by muse, mutect2, varscan2
- SMARCA4 | c.1599A>C p.E533D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60804476; called by muse, mutect2
- SSR3 | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.584); catalogued as COSV99411188; called by muse, mutect2
- TMEM243 | c.209T>C p.L70S | Missense Mutation (SNP) | VAF 140/380 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57539118; called by muse, mutect2
- TTN | c.82951A>G p.I27651V (on ENST00000591111; = p.I20227V on NM_003319.4) | Missense Mutation (SNP) | VAF 40/784 reads (5%) | PolyPhen benign (0.015); catalogued as rs1445509592, COSV60243546; called by muse, mutect2
- WDR17 | c.2762A>G p.H921R | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as rs1033407126, COSV54579693; called by muse, mutect2
- XYLT1 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374020411, COSV54479975; called by muse, mutect2, varscan2
- ZCCHC9 | c.152A>G p.N51S | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54176829; called by muse, mutect2, varscan2
- ZNF175 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs1381490687, COSV51797479; called by muse, mutect2, varscan2
- BCL2L12 | c.237del p.G80Dfs*19 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- CARD11 | c.1479_1498del p.H494Efs*37 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- CDH23 | c.7935del p.N2645Kfs*9 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- COL22A1 | c.3668_3672del p.K1223Rfs*86 | Frame Shift Del (DEL) | VAF 56/192 reads (29%) | called by mutect2, pindel, varscan2
- MUC5B | c.7226G>T p.C2409F | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- PPP4R4 | c.2621_*10delinsC | Nonstop Mutation (DEL) | VAF 49/296 reads (17%) | called by pindel, varscan2*
- TDRD5 | c.1578del p.Q527Sfs*8 | Frame Shift Del (DEL) | VAF 58/659 reads (9%) | called by mutect2, pindel
- TP63 | c.1875_1898del p.V626_T633del | In Frame Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- WDFY3 | c.9343_9363+4del p.X3115_splice | Splice Site (DEL) | VAF 34/252 reads (13%) | called by pindel, varscan2
- ADAM32 | c.2112G>A p.R704= | Silent (SNP) | VAF 11/236 reads (5%) | catalogued as COSV65947584; called by muse, mutect2
- BLMH | c.1104A>G p.S368= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs1446846251, COSV55586518; called by muse, mutect2, varscan2
- COMP | c.177C>T p.I59= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55876049; called by muse, mutect2, varscan2
- HSPA4L | c.924A>G p.Q308= | Silent (SNP) | VAF 135/433 reads (31%) | catalogued as COSV56547444; called by muse, mutect2, varscan2
- PARP4 | c.255A>G p.R85= | Silent (SNP) | VAF 140/458 reads (31%) | catalogued as COSV67963428; called by muse, mutect2, varscan2
- PPM1K | c.528C>T p.R176= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV55797323; called by muse, mutect2
- PRDM14 | c.429T>C p.C143= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52574630; called by muse, mutect2, varscan2
- PRSS55 | c.843C>A p.T281= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV60808999, COSV60809323; called by muse, mutect2, varscan2
- RFFL | c.385C>T p.L129= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV52073360; called by muse, mutect2, varscan2
- RFWD3 | c.351G>A p.L117= | Silent (SNP) | VAF 10/252 reads (4%) | catalogued as COSV63097196, COSV63098802; called by muse, mutect2
- RIMS2 | c.135T>C p.D45= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV68493558; called by muse, mutect2, varscan2
- TBC1D12 | c.2037T>C p.D679= | Silent (SNP) | VAF 172/532 reads (32%) | catalogued as COSV56556776; called by muse, mutect2, varscan2
- TNC | c.5337C>A p.I1779= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as COSV60788623; called by muse, varscan2
- ZBBX | c.720T>C p.R240= | Silent (SNP) | VAF 204/611 reads (33%) | catalogued as COSV56797133; called by muse, mutect2, varscan2
